Somatic mutation profile of tumor specimen TCGA-61-2009-01A (aliquot TCGA-61-2009-01A-01W-0722-08) from TCGA case TCGA-61-2009, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.1 years (23,772 days).
Specimen TCGA-61-2009-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c5480ab-9f11-4a72-becf-a9b0b8360993.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2009-10A (Blood Derived Normal), aliquot TCGA-61-2009-10A-01W-0722-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d954a1cf-e7d3-4415-bf2f-9ae0328470d6

The open-access MAF lists 81 somatic variants for this specimen: 71 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 62, Silent 10, Frame Shift Del 4, Nonsense Mutation 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 10/84 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 40/92 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.2176G>T p.D726Y | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52194979, COSV52214022; called by muse, mutect2, varscan2
- ACTR6 | c.809T>G p.L270W | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51843631; called by muse, mutect2, varscan2
- ARHGAP35 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68336836; called by muse, mutect2, varscan2
- B3GNT4 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV57337759; called by muse, mutect2, varscan2
- BUB3 | c.695A>G p.E232G | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1451912111, COSV64364284; called by muse, mutect2, varscan2
- CAPN13 | c.390C>G p.F130L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54430097, COSV54436213; called by muse, mutect2, varscan2
- CARTPT | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV57115969; called by muse, mutect2, varscan2
- CCDC91 | c.718A>G p.I240V | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.968); catalogued as rs763387977, COSV100081731; called by muse, mutect2, varscan2
- CDH11 | c.1418C>G p.P473R | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV51780053; called by muse, mutect2, varscan2
- CDK19 | c.269A>G p.D90G | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV60454286; called by muse, mutect2, varscan2
- CHD8 | c.1216G>C p.A406P (on ENST00000646647 / NM_001170629.2; = p.A127P on NM_020920.4) | Missense Mutation (SNP) | VAF 86/119 reads (72%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.636); catalogued as rs1211379673, COSV67873053; called by muse, mutect2, varscan2
- CILP | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.06); catalogued as rs760076237, COSV56028605; called by muse, mutect2, varscan2
- COL6A5 | c.6113A>G p.Q2038R (on ENST00000312481; = p.Q2034R on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1254637692, COSV55218543; called by muse, mutect2
- COL6A6 | c.2795C>T p.T932M | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs377667400; called by muse, mutect2, varscan2
- CPAMD8 | c.3153dup p.H1052Afs*30 (on ENST00000651564; = p.H1005Afs*30 on NM_015692.5) | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | catalogued as rs750161916; called by mutect2, varscan2
- DCT | c.435A>C p.L145F | Missense Mutation (SNP) | VAF 62/357 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as COSV65471006; called by muse, mutect2, varscan2
- DNAH7 | c.11629G>C p.G3877R | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100415005; called by muse, mutect2, varscan2
- DSG1 | c.2957C>T p.A986V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.059); catalogued as COSV99935947; called by muse, mutect2
- EPX | c.1984C>A p.Q662K | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56599785; called by muse, mutect2, varscan2
- ETV6 | c.1123G>C p.G375R | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765416, COSV56766903, COSV56766981; called by muse, mutect2, varscan2
- EVI2A | c.46T>C p.F16L | Missense Mutation (SNP) | VAF 226/362 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.044); catalogued as COSV55987200; called by muse, mutect2, varscan2
- FAT3 | c.2273A>G p.N758S | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs375393993; called by muse, mutect2, varscan2
- FETUB | c.736T>A p.W246R | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99408982; called by muse, mutect2
- FIGNL1 | c.1319T>G p.F440C | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764605600, COSV63554204; called by muse, mutect2, varscan2
- FLG | c.10474G>T p.D3492Y | Missense Mutation (SNP) | VAF 37/343 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV64251553; called by muse, mutect2, varscan2
- HAO1 | c.802G>T p.V268L | Missense Mutation (SNP) | VAF 10/147 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV66491076, COSV66491237; called by muse, mutect2
- HELZ | c.366G>T p.E122D | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.829); catalogued as COSV62381373; called by muse, varscan2
- IQCC | c.98A>T p.Y33F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV52211788; called by muse, mutect2, varscan2
- ITGA3 | c.1091C>G p.P364R | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV50319433, COSV50348205; called by muse, mutect2, varscan2
- KCTD14 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.636); catalogued as rs752112333, COSV62001096, COSV99074518; called by muse, mutect2, varscan2
- KIF3B | c.1825G>T p.E609* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV65229624; called by muse, mutect2, varscan2
- KRTAP9-8 | c.347G>C p.C116S | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV54201179; called by muse, mutect2, varscan2
- LMO7 | c.957C>A p.D319E (on ENST00000357063; = p.D334E on NM_005358.5) | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.99); PolyPhen benign (0.136); catalogued as COSV100413021; called by muse, mutect2
- LRRC7 | c.328C>G p.R110G (on ENST00000651989 / NM_001370785.2; = p.R77G on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV50415481, COSV50652183; called by muse, mutect2, varscan2
- MASP2 | c.1636A>T p.S546C | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV53571491; called by muse, mutect2, varscan2
- MBNL1 | c.95C>G p.T32R | Missense Mutation (SNP) | VAF 15/302 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.168); catalogued as COSV99220304; called by muse, mutect2
- MYO5B | c.1855C>A p.P619T | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs769626838, COSV53215714; called by muse, mutect2, varscan2
- NUP210 | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV54415317; called by muse, mutect2, varscan2
- OMG | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 39/284 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as COSV55988815; called by muse, mutect2, varscan2
- OR1L8 | c.166C>G p.L56V | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV59186034, COSV59187614; called by muse, mutect2, varscan2
- ORC1 | c.951C>G p.I317M | Missense Mutation (SNP) | VAF 54/258 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.188); catalogued as COSV65365438; called by muse, mutect2, varscan2
- OVCH1 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 59/440 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.343); catalogued as COSV58968927; called by muse, mutect2, varscan2
- PCDHGC5 | c.2084T>A p.I695N | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52773579; called by muse, mutect2, varscan2
- PIWIL3 | c.2130A>C p.K710N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.159); catalogued as COSV100177590; called by muse, mutect2, varscan2
- PLA2R1 | c.2401+1G>A p.X801_splice | Splice Site (SNP) | VAF 12/64 reads (19%) | catalogued as COSV51788151; called by muse, varscan2
- PLAU | c.272G>T p.C91F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65642230; called by muse, mutect2, varscan2
- PLXNC1 | c.1268C>A p.T423K | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.33); catalogued as COSV99313011; called by muse, mutect2
- PRKACG | c.112A>T p.T38S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV99598670; called by muse, mutect2, varscan2
- PRUNE1 | c.1209G>C p.E403D | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV54849412; called by muse, mutect2, varscan2
- PTPRT | c.2636C>T p.T879M | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757402269, COSV61962744; called by muse, mutect2
- RAPGEF5 | c.1238G>A p.R413Q (on ENST00000401957 / NM_001367602.2; = p.R716Q on NM_012294.5) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1423271416, COSV100687979, COSV59791924; called by muse, mutect2, varscan2
- SEC13 | c.128G>A p.R43H (on ENST00000350697 / NM_183352.3; = p.R46H on NM_030673.4) | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.117); catalogued as rs201150723, COSV61601598; called by muse, mutect2, varscan2
- SENP6 | c.1168G>C p.E390Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as COSV100519136; called by muse, mutect2
- SLC38A4 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs562561657, COSV56972080; called by muse, mutect2, varscan2
- SLC5A9 | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 27/141 reads (19%) | catalogued as rs199760707; called by muse, mutect2, varscan2
- ST3GAL3 | c.406C>T p.R136W (on ENST00000361392 / NM_174964.4; = p.R121W on NM_006279.5) | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.901); catalogued as rs1416679783, COSV53515433; called by muse, mutect2, varscan2
- TAT | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs548790465, COSV63533663; called by muse, mutect2, varscan2
- TEX55 | c.262G>T p.G88C | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV55213162; called by muse, mutect2, varscan2
- TGFBR2 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.581); catalogued as rs1553631704, COSV55445508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNC | c.2336A>T p.Y779F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60791661; called by muse, mutect2, varscan2
- UGT2B7 | c.1310+1G>C p.X437_splice | Splice Site (SNP) | VAF 9/52 reads (17%) | catalogued as COSV59441759, COSV59445888; called by muse, mutect2, varscan2
- UTP14C | c.1385C>T p.S462F | Missense Mutation (SNP) | VAF 73/145 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV73000840; called by muse, mutect2, varscan2
- WDFY3 | c.1232A>C p.Y411S | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55716203; called by muse, mutect2, varscan2
- ZNF70 | c.1220T>C p.I407T | Missense Mutation (SNP) | VAF 26/172 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.036); catalogued as rs1569134281, COSV59534209; called by muse, mutect2, varscan2
- LRP1B | c.6084del p.S2029Qfs*7 | Frame Shift Del (DEL) | VAF 20/100 reads (20%) | called by mutect2, pindel, varscan2
- NELFA | c.1568_1574del p.T523Sfs*11 (on ENST00000542778; = p.T512Sfs*11 on NM_005663.5) | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- SMG1 | c.2708_2709del p.R903Qfs*25 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- SUMF2 | c.322del p.M108Cfs*16 (on ENST00000652303; = p.M89Cfs*16 on NM_015411.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- TUBGCP4 | c.1129C>G p.Q377E | Missense Mutation (SNP) | VAF 23/778 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.055); called by muse, mutect2
- ADAMTS17 | c.1200C>T p.D400= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs753792500, COSV51481242; called by mutect2, varscan2
- DDX24 | c.2001C>T p.T667= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs369246793; called by muse, mutect2, varscan2
- EPB41L1 | c.1743C>T p.G581= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs1231097398, COSV52446306; called by muse, mutect2, varscan2
- FASTKD2 | c.1107G>C p.V369= | Silent (SNP) | VAF 52/331 reads (16%) | catalogued as COSV52700565; called by muse, mutect2, varscan2
- FBN2 | c.1899C>T p.I633= | Silent (SNP) | VAF 93/244 reads (38%) | catalogued as COSV52549483; called by muse, mutect2, varscan2
- PPOX | c.1428C>T p.N476= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as COSV60528363; called by muse, mutect2, varscan2
- TEX14 | c.3132T>C p.H1044= (on ENST00000240361 / NM_001201457.2; = p.H1038= on NM_031272.5) | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as COSV53628229; called by muse, mutect2, varscan2
- VWF | c.7983G>A p.L2661= | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as COSV99778901; called by muse, mutect2
- ZDBF2 | c.696T>C p.D232= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as rs1462921701, COSV65630773; called by muse, mutect2, varscan2
- ZFHX3 | c.8556C>T p.N2852= | Silent (SNP) | VAF 24/234 reads (10%) | catalogued as rs749610266, COSV99199242; called by muse, mutect2
